Surgical pathology report (de-identified scan), TCGA case TCGA-19-1791, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-1791-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS

A-E. RIGHT FRONTAL LOBE OF BRAIN, LESIONS NUMBER ONE AND TWO, AND SPECIMENS LABELED PATH [REDACTED], AND [REDACTED]; BIOPSIES:

-- HIGH-GRADE ASTROCYTOMA, CONSISTENT WITH DERIVATION FROM GLIOBLASTOMA MULTIFORME

F. SPECIMEN LABELED [REDACTED], BIOPSY:

-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

Note: Focal microvascular proliferation is identified.

Electronically Signed Out By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consult Diagnosis

A: Touch Imprint & Microscopic: High grade glioma.

Clinical History:

Right sided tumor

Specimens Submitted As:

A: RIGHT FRONTAL LESION #1

B: RIGHT FRONTAL LESION #2

C: PATH [REDACTED]

D: CORE [REDACTED]

E: EDGE [REDACTED]

F: WM [REDACTED]

Gross Description:

A: Received fresh for intraoperative consultation, labelled with the patient's name and number, and "right frontal lesion #1", is an irregular fragment of white-tan to pink-tan, soft tissue, 0.6 x 0.4 x 0.4 cm. The specimen is bisected. Cut surface is white-tan to pink-tan. A frozen section is performed. The specimen is submitted entirely in two cassettes.

B: Received fresh for intraoperative consultation, labelled with the patient's name and number, and "right frontal lesion #2", are two, irregular fragments of white-tan to pink-tan, soft tissue, 0.6 x 0.4 x 0.3 cm and 0.6 x 0.4 x 0.4 cm. Both fragments are bisected. Cut surface is white-tan to pink-tan. A frozen section is performed. The specimen is submitted entirely in two cassettes.

C: Received in formalin labeled with the patient's name and number, are multiple irregular, pink-tan to red-brown, soft, cerebriform tissue fragments measuring in aggregate 3.0 x 2.8 x 0.5 cm. Submitted in toto in two cassettes.

D: Received in formalin labeled with the patient's name and number, are two irregular, pink-tan, soft, cerebriform tissue fragments measuring 1.0 x 0.8 x 0.2 cm and 1.4 x 0.4 x 0.4 cm. Submitted in toto in one cassette.

[page 2 of 2]
E:Received in formalin labeled with the patient's name and number, are multiple irregular, pink-tan to red-brown, soft tissue fragments measuring in aggregate 1.8 x 1.0 x 0.4 cm. Submitted in toto in one cassette.

F:Received in formalin labeled with the patient's name and number, are multiple irregular, opaque white to pink-tan, soft, cerebriform tissue fragments measuring in aggregate 2.3 x 2.2 x 0.45 cm. Submitted entirely in two cassettes.

Summary of Cassettes:

A	1FS	
	2	remainder of the specimen
B	1FS	
	2	remainder of the specimen

TCGA-19-1791

Source: NCI Genomic Data Commons file cccb55e6-d91a-4670-8e68-cb40c7f8f623 (TCGA-19-1791.DC971FBF-7F2E-4257-AF89-E5039838F6A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).